Gene-level copy-number profile of tumor specimen ALCH-ABN3-TTP1-A from ALCHEMIST case ALCH-ABN3, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.9 years (22,239 days).
Specimen ALCH-ABN3-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 710c87d0-a5bd-4941-9d63-4ef4c49f29da.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ABN3-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/532ff5b3-4a9b-4ae2-b5ec-94cd3b57da5f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 260; copy number 1: 7,940; copy number 2: 47,446; copy number 3: 3,216; copy number 4: 38; copy number 5: 6; copy number 8: 1.

Homozygous deletions (total copy number 0; autosomes only): 51 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:52,573,114–52,573,816, 1 gene: EEF1GP7.
- chr1:182,086,551–182,090,112, 1 gene: AL355482.2.
- chr2:42,532,766–42,533,442, 1 gene (within-gene range 0–2): AC025750.1.
- chr6:109,390,215–109,443,919, 2 genes: PPIL6, SMPD2.
- chr7:102,433,106–102,456,825, 1 gene (within-gene range 0–2): ORAI2.
- chr9:19,089,593–19,089,688, 1 gene (within-gene range 0–2): Y_RNA.
- chr10:133,246,478–133,247,891, 2 genes: MIR202HG, MIR202.
- chr12:37,575,587–37,576,384, 1 gene: ZNF970P.
- chr12:93,266,017–93,266,096, 1 gene: AC126172.1.
- chr14:18,333,726–18,412,264, 3 genes: CR383658.1, RNU6-458P, CR383658.2.
- chr14:18,555,677–18,650,966, 13 genes: CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11.
- chr16:1,317,891–1,322,845, 1 gene (within-gene range 0–2): AL031714.1.
- chr16:89,873,570–89,913,627, 1 gene (within-gene range 0–2): TCF25.
- chr18:856,526–857,045, 1 gene: AP000894.1.
- chr18:12,400,412–12,437,635, 3 genes: RNU7-129P, PRELID3A, AP001029.1.
- chr18:79,420,836–79,422,780, 1 gene (within-gene range 0–1): AC018445.3.
- chr19:11,466,240–11,529,172, 7 genes (within-gene range 0–1): AC008481.3, ZNF653, MIR7974, ECSIT, RN7SL833P, AC008481.2, AC008481.1.
- chr19:19,254,748–19,273,369, 3 genes (within-gene range 0–2): AC138430.1, HAPLN4, AC138430.2.
- chr19:35,124,513–35,142,451, 1 gene (within-gene range 0–1): LGI4.
- chr19:39,196,964–39,204,263, 2 genes: NCCRP1, SYCN.
- chr21:12,999,676–13,113,790, 4 genes: AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–95,683, 2 genes, copy number 5 (within-gene range 3–5): AC093627.1, AC093627.6.
- chr21:43,414,483–43,427,131, 1 gene, copy number 8: SIK1.
- chr22:18,936,411–18,959,512, 2 genes, copy number 5 (within-gene range 1–5): AC007326.5, AC007326.2.

Autosomal genes at a single copy (total copy number 1): 5,332. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
